Surgical pathology report (de-identified scan), TCGA case TCGA-67-3772, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site St Joseph's Medical Center (MD), specimen TCGA-67-3772-01A (Primary Tumor).

[page 1 of 8]
IT AGE AT RECEIPT

TISSUES:

- A. LYMPH NODE
- B. LYMPH NODE
- C. LUNG-RIGHT UPPER LOBE
- D. LYMPH NODE
- E. LYMPH NODE

CODES: P88305 - 88305
P88309 - 88309
P88331 - 88331
D50175 - RESECTION
D50177 - REGIONAL LYMPH
88305TC - LEVEL IV - GROS
88309TC - LEVEL VI - GROS
88331TC - PATHOLOGY CONSU
88342TC - IMMUNOPEROXIDAS
1 - SURGICAL SPECIM
T08000 - LYMPH NODE
T28200 - RT UP LOBE LUNG
T28200/M81403 - RT UP LOBE LUNG/ADENOCARCINOMA,

ICD CODES: 162.9 - MAL NEO BRONCH/LUNG NOS

MARKERS: 88305, 88305TC, 88309, 88309TC, 88331, PATH CONSULT FS, IMMUNOPEROXIDASE, RES, RLN,
SURGICAL SPECIMEN

Continued on next page ...

[page 2 of 8]
00/21/03 0317 11:12:22
[REDACTED] [REDACTED] [REDACTED]

CLINICAL HISTORY

PERTINENT CLINICAL HISTORY: RT LUNG CA
[REDACTED]

FINAL DIAGNOSIS

- A. RIGHT DIAPHRAGMATIC NODULE, BIOPSY:
- FIBROADIPOSE TISSUE WITH MESOTHELIAL PROLIFERATION AND CHRONIC INFLAMMATION.
- NO MALIGNANCY IS IDENTIFIED.
- B. LYMPH NODE, RIGHT SUPERIOR HILAR 10R:
- THREE LYMPH NODES, NEGATIVE FOR TUMOR.
- C. LUNG, RIGHT UPPER LOBE, LOBECTOMY:
- MODERATELY DIFFERENTIATED ADENOCARCINOMA WITH FOCAL PAPILLARY FEATURES, SEE SYNOPTIC REPORT.
- D. LUNG, RIGHT UPPER NODE:
- MATTED LYMPH NODE, NEGATIVE FOR TUMOR.
- E. LYMPH NODE, RIGHT POSTERIOR SUPERIOR HILAR:
- LYMPH NODE, NEGATIVE FOR TUMOR.
- [REDACTED]

Continued on next page ...

[page 3 of 8]
GROSS DESCRIPTION

A. The specimen is submitted fresh for frozen section as "right diaphragmatic nodule" and consists of five tan tissue fragments ranging from 0.2 to 0.3 cm in dimension; submitted 5 (1) labeled "FSP" for frozen section.

FROZEN SECTION DIAGNOSIS: Focal cluster of atypical cells of uncertain nature; ? mesothelial cells, dissimilar to primary lung adenocarcinoma in recent aspiration

B. The specimen is submitted fresh for frozen section as "right superior hilar node 10R" and consists of three red black nodes ranging from 0.7 to 1.1 cm in dimension. Each is sectioned and the specimen submitted in toto, 5 (1) labeled "FSP" for frozen section.

FROZEN SECTION DIAGNOSIS: Negative for tumor.

C. The specimen is submitted fresh as "right upper lobe" and consists of a 131 gram (416), 16 x 7 x 3 cm lung lobe. The pleural surface shows a 2.2 x 2 cm firm puckered indurated area. The pleural surface overlying this area is inked blue. The pleural surface also shows four ill-defined tan white firm subpleural nodules measuring 0.3 to 0.4 cm with the closest located 6.5 cm from the puckered area. The specimen is received with multiple stapled margins measuring 3.5 to 7 cm in length along with a stapled bronchial margin measuring 2.5 cm in diameter and several adjacent stapled vascular margins measuring 0.2 cm in length x 0.5 cm in diameter to 0.5 cm in length x 1 cm in diameter. The stapled margins are removed and the underlying parenchyma inked black. Sectioning reveals a 4.3 x 3 x 2.2 cm well circumscribed tan yellow to white firm, focally hemorrhagic mass corresponding to the previous described puckered and indurated area on the pleural surface grossly appearing to abut the pleural surface measuring 0.7 cm from the closest black inked parenchyma underlying the stapled resection margin and 3 cm from the bronchial margin. The remaining parenchyma is red to maroon, spongy, homogenous and grossly unremarkable. No other discrete masses or nodularities are grossly evident. Also identified at the hilum is a 1 cm in greatest dimension gray black possible hilar lymph node which is trisected and submitted entirely. Representative sections are submitted, multiple (7) as follows:

Cassette 1:	Vasculature and bronchial margins submitted en face
Cassette 2:	Subpleural nodules submitted entirely
Cassette 3:	Mass with closest pleural surface
Cassette 4:	Perpendicular section of mass to the closest stapled resection margin

Continued on next page ...

[page 4 of 8]
GROSS DESCRIPTION

(Continued)

Cassette 5: Additional section of mass with adjacent uninvolved
parenchyma
Cassette 6: Uninvolved parenchyma
Cassette 7: One possible hilar lymph node, trisected

D. The specimen is submitted fresh as "right upper node" and consists of a cluster of multiple gray black to deep red nodules ranging from 0.3 to 0.7 cm in dimension, the individual nodes separated and the specimen submitted in toto, multiple (1).

E. The specimen is submitted fresh as "right posterior superior hilar node" and consists of a single deep red 1.1 cm nodule, bisected and submitted in toto, 2 (1).

PRIORITY

PRIORITY: FROZEN SEC

SURGICAL PROCEDURES:

RESECTION, REGIONAL LYMPH

SYNOPTIC REPORT

SYNOPTIC REPORT: LUNG
(CAP/AJCC/ACS - REQUIRED ELEMENTS)

SPECIMEN TYPE: LOBECTOMY

LATERALITY: RIGHT

TUMOR SITE: RIGHT UPPER LOBE

TUMOR SIZE: 4.3 CM

HISTOLOGIC TYPE: ADENOCARCINOMA WITH FOCAL PAPILLARY FEATURES

HISTOLOGIC GRADE: 2 (MODERATELY DIFFERENTIATED)

EXTENT OF INVASION: TUMOR INVADES VISCERAL PLEURA

EXTENSION TO PLEURA/OTHER STRUCTURES: NONE IDENTIFIED

MARGINS:

BRONCHIAL: UNINVOLVED

PARENCHYMAL: UNINVOLVED

VASCULAR: UNINVOLVED

Continued on next page ...

[page 5 of 8]
SYNOPTIC REPORT

(Continued)

DISTANCE TO PERTINENT MARGIN: 3 CM FROM THE BRONCHIAL MARGIN

VENOUS INVASION: ABSENT

ARTERIAL (LARGE VESSEL) INVASION: ABSENT .

LYMPH NODE:

N1 - # INVOLVED/# EXAMINED: 0/6

N2 - # INVOLVED/#EXAMINED: 0/8

N3 - # INVOLVED/# EXAMINED: 0/0

OTHER PERTINENT FINDINGS:

- INCIDENTAL PULMONARY MENINGOTHELIAL-LIKE NODULES/CHEMODECTOMAS (0.3-0.4 CM). THESE ARE PR+, CD56+ AND CHROMOGRANIN-.

pTNM STAGE: pT2 N0 (AJCC 6TH ADDITION)

Unless otherwise specified, the performance characteristics of the immunoperoxidase stains performed here have been confirmed by the St. [REDACTED]. These tests have not been cleared or approved by the U.S. Food and Drug Administration, although such approval is not necessary.

Prelim

Final

*** End of Report ***

[page 6 of 8]
ORDERED: N A 4+1+1, C88173, C88305, C88342, FNA EVALUATION, LEVEL IV - GROS,
IMMUNOPEROXIDAS

CLINICAL HISTORY

HISTORY: RUL CAVITARY MASS (2 CM) PICKED UP AS AN INCIDENTAL FINDING ON CT SCAN.
RENAL MASS - CRYO ABLATION
X-RAY FINDINGS: 2 CM RUL LUNG MASS.

GROSS DESCRIPTION

RECEIVED: Slide 40 cc Fluid* X Fresh Fixed Type Fix

* Volume may reflect total of specimen, fixative, and/or collection fluid.

APPEARANCE: X Clear Cloudy Foamy Bloody

Clotted Tissue Color COLORLESS

PREP: 6 Smear(s) Diff Quick(s) Filter(s) 1 Cell Block(s)

Cytospin(s) - 2 Singles(s) Double(s)

H&E Unstained

Comment:

FINAL DIAGNOSIS

LUNG, RIGHT UPPER LOBE, NEEDLE ASPIRATION BIOPSY:

- POSITIVE FOR MALIGNANT CELLS.
- ADENOCARCINOMA CONSISTENT WITH LUNG PRIMARY.

COMMENT: THE TUMOR SHOWS GLAND FORMATION AND APPEARS MODERATELY
DIFFERENTIATED. A TTF-1 STAIN IS POSITIVE.

THE TUMOR MORPHOLOGY IS DISSIMILAR TO THE TUMOR IN THE KIDNEY

[page 7 of 8]
SURGICAL PROCEDURES:
REGIONAL LYMPH

CLINICAL HISTORY

PERTINENT CLINICAL HISTORY: NON-SMALL CELL LUNG CA, RIGHT.

GROSS DESCRIPTION

A. The specimen is submitted fresh as "4L left lower paratracheal" and consists of three pink to red lymph nodes ranging 0.2 cm to 0.8 cm in dimension. The largest lymph node is bisected. The specimen is submitted in toto, 4 (1). The largest lymph node is inked with blue dye.

B. The specimen is submitted fresh as "10L left tracheobronchial angle" and consists of a 0.6 cm grey black lymph node; bisected and submitted, 2 (1).

C. The specimen is submitted fresh as "2R right upper paratracheal" and consists of multiple segments of adipose tissue intermixed with pink to red possible lymph nodes with aggregate dimension 2 x 1.5 x 0.4 cm with the lymph nodes measuring up to approximately 0.4 cm. The specimen is submitted in toto, multiple (1).

D. The specimen is submitted fresh as "4R right lower paratracheal" and consists of multiple segments of yellow adipose tissue intermixed with pink to purple tan lymph nodes with aggregate dimension 2.3 x 1.6 x 0.4 cm with the lymph nodes measuring up to 0.5 cm; submitted, multiple (1).

E. The specimen is submitted fresh as "3A lower pretracheal" and consists of multiple segments of yellow adipose tissue intermixed with pink lymph nodes with aggregate dimension 2 x 1.5 x 0.4 cm with the lymph nodes measuring up to approximately 0.5 cm; submitted, multiple (1).

F. The specimen is submitted fresh as "7 subcarinal" and consists of multiple segments of yellow adipose tissue intermixed with pink to red lymph nodes with aggregate dimension 2 x 2 x 0.3 cm with the lymph nodes measuring up to approximately 0.4 cm; submitted, multiple (1).

[page 8 of 8]
GROSS DESCRIPTION

(Continued)

G. The specimen is submitted fresh as "2L left upper paratracheal" and consists of a segment of adipose tissue measuring 1.5 x 1 x 0.2 cm with a single red to pink elongate lymph node measuring 0.8 cm. The lymph node is bisected and submitted, 2 (1).

FINAL DIAGNOSIS

- A. 4L LEFT LOWER PARATRACHEAL:
- THREE LYMPH NODES SHOWING ANTHRACOSIS; NEGATIVE FOR TUMOR (0/3).
- B. 10L LEFT TRACHEOBRONCHIAL ANGLE:
- SINGLE LYMPH NODE SHOWING ANTHRACOSIS; NEGATIVE FOR TUMOR (0/1).
- C. 2R RIGHT UPPER PARATRACHEAL:
- MULTIPLE SMALL LYMPH NODES SHOWING ANTHRACOSIS; NEGATIVE FOR TUMOR.
- D. 4R RIGHT LOWER PARATRACHEAL:
- MULTIPLE SMALL LYMPH NODES SHOWING ANTHRACOSIS; NEGATIVE FOR TUMOR.
- E. 3A LOWER PRETRACHEAL:
- MULTIPLE SMALL LYMPH NODES SHOWING ANTHRACOSIS; NEGATIVE FOR TUMOR.
- F. 7 SUBCARINAL:
- MULTIPLE SMALL LYMPH NODES SHOWING ANTHRACOSIS; NEGATIVE FOR TUMOR.
- G. 2L LEFT UPPER PARATRACHEAL:
- SINGLE LYMPH NODE AND ADJACENT ADIPOSE TISSUE, NEGATIVE FOR TUMOR (0/1).

Source: NCI Genomic Data Commons file f06f6fe3-1750-4d93-949c-623ea6766f42 (TCGA-67-3772.1B3A5B8E-7469-4FD6-B314-AD1FD7A2B957.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).